Somatic mutation profile of tumor specimen TCGA-2K-A9WE-01A (aliquot TCGA-2K-A9WE-01A-11D-A382-10) from TCGA case TCGA-2K-A9WE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 53.7 years (19,603 days).
Specimen TCGA-2K-A9WE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd2ecf79-5ef4-41b7-921f-ffa798338985.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2K-A9WE-10A (Blood Derived Normal), aliquot TCGA-2K-A9WE-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6ba9132-ace6-4c68-8c05-15dd0e131a55

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 2, Intron 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJAP1 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981949; called by muse, mutect2
- AMOTL1 | c.1656A>C p.E552D | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV100504622; called by muse, mutect2
- ARHGAP22 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV50933776; called by muse, mutect2
- C1orf54 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 12/107 reads (11%) | catalogued as rs1553851877, COSV100810020; called by muse, mutect2, varscan2
- CA12 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99458582; called by muse, mutect2, varscan2
- CDK11A | c.2017C>G p.R673G (on ENST00000378633 / NM_001313896.2; = p.R670G on NM_024011.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99319362; called by muse, varscan2
- CEP192 | c.4718C>T p.S1573F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100381779; called by muse, mutect2, varscan2
- DNAAF5 | c.902T>A p.V301D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99860132; called by muse, mutect2, varscan2
- DNAH5 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99452371; called by muse, mutect2
- DUSP7 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99623595; called by muse, mutect2, varscan2
- EGFLAM | c.701T>A p.I234N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV100472822; called by muse, mutect2, varscan2
- F2RL1 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99688855; called by muse, mutect2, varscan2
- FBXL8 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV99263581; called by muse, mutect2
- GPR162 | c.812A>C p.N271T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.762); catalogued as COSV99163850; called by muse, mutect2, varscan2
- GTPBP2 | c.400G>T p.V134F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1365848266, COSV100200069; called by muse, mutect2, varscan2
- HS3ST6 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562817; called by muse, mutect2
- IKZF3 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99500010; called by muse, mutect2
- KAT6A | c.5566T>C p.S1856P | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99705624; called by muse, mutect2, varscan2
- MEGF8 | c.1747G>C p.A583P | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.374); catalogued as COSV99238140; called by muse, mutect2, varscan2
- MEP1A | c.207A>T p.R69S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV100042958; called by muse, mutect2, varscan2
- MOV10 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs963236566, COSV62491073; called by muse, mutect2
- NRBP1 | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV99275193; called by muse, mutect2, varscan2
- PDE1C | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100373304; called by muse, mutect2, varscan2
- PRCP | c.1469A>T p.D490V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV100476257; called by muse, mutect2
- PTPRZ1 | c.5827T>G p.Y1943D | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101100579; called by muse, mutect2, varscan2
- RANBP2 | c.4495T>C p.C1499R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99312832; called by muse, mutect2, varscan2
- RXRA | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100709330; called by muse, mutect2
- SLC30A8 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.257); catalogued as COSV101438697; called by muse, mutect2, varscan2
- STK17A | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV100082238; called by muse, mutect2
- TRAK2 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100217029; called by muse, mutect2
- TTC17 | c.2518T>C p.F840L | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV99235735; called by muse, mutect2, varscan2
- TUBGCP6 | c.3608C>T p.S1203L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as COSV99956053; called by mutect2, varscan2
- VSIG2 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99423395; called by muse, mutect2, varscan2
- ZFAND4 | c.1937C>G p.T646S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100763058; called by muse, mutect2, varscan2
- ZNF235 | c.851_852insC p.H285Tfs*10 | Frame Shift Ins (INS) | VAF 18/170 reads (11%) | catalogued as COSV99349643; called by mutect2, pindel, varscan2
- ZNF606 | c.1977A>C p.K659N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071927, COSV100071973; called by muse, mutect2
- ZNF831 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100926161; called by muse, mutect2
- BMPR1A | c.511del p.S171Pfs*36 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- CBX5 | c.569del p.K190Rfs*111 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.10492T>A p.C3498S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCCS | c.47del p.N16Mfs*17 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- MCRS1 | c.289-5_289del p.X97_splice | Splice Site (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- PHC2 | c.87C>A p.C29* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- RNF208 | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2
- SESN3 | c.806del p.M269Rfs*18 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- TRHDE | c.221_231del p.P74Rfs*146 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ALDOB | c.837T>C p.D279= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV100878905; called by muse, mutect2
- CFAP92 | c.1008A>G p.R336= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99414853; called by mutect2, varscan2
- CHD9 | c.5433T>C p.P1811= | Silent (SNP) | VAF 19/200 reads (10%) | catalogued as COSV99529506; called by muse, mutect2, varscan2
- CLTC | c.2571G>C p.L857= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99292681; called by muse, mutect2, varscan2
- HELZ | c.2341T>C p.L781= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as rs997027891, COSV100698951; called by muse, mutect2, varscan2
- NCOR1 | c.5988T>G p.V1996= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV99251317; called by muse, mutect2
- OR56A4 | c.738C>T p.D246= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs1259505196, COSV100417565; called by muse, mutect2
- PCNX1 | c.3438A>G p.Q1146= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99456640; called by muse, mutect2
- SLC39A7 | c.654T>A p.S218= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as COSV100807815; called by muse, mutect2
- USP10 | c.1575G>A p.E525= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99551696; called by muse, mutect2
- WDR33 | c.141A>T p.R47= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100460453; called by muse, mutect2
- AGAP7P | n.1200A>G | RNA (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- CTNS | c.*332T>C | 3'UTR (SNP) | VAF 18/174 reads (10%) | catalogued as COSV99251475; called by muse, mutect2
- MBNL1 | c.174+40244C>T | Intron (SNP) | VAF 25/303 reads (8%) | catalogued as COSV99221015; called by muse, mutect2
